Somatic mutation profile of tumor specimen 436297af-feb7-4754-96b7-c5bfb5 (aliquot 436297af-feb7-4754-96b7-c5bfb5_D6_1) from CPTAC case 18BR003, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.8 years (24,029 days).
Specimen 436297af-feb7-4754-96b7-c5bfb5: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40fbcc5f-4c57-48d6-959b-4fdfd21f5186.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen a0935138-0a31-4b38-a750-2914be (Blood Derived Normal), aliquot a0935138-0a31-4b38-a750-2914be_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79149624-2d04-45f6-8650-3a4d730996a5

The open-access MAF lists 1,191 somatic variants for this specimen: 731 protein-altering or splice-affecting, 308 silent, 152 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 647, Silent 308, Intron 74, Nonsense Mutation 59, 5'UTR 23, 3'UTR 20, RNA 16, 5'Flank 12, Splice Region 12, Splice Site 9, 3'Flank 7, Nonstop Mutation 2.

Variants (750 of 1,191; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.4684C>T p.Q1562* | Nonsense Mutation (SNP) | VAF 15/127 reads (12%) | catalogued as rs397507737, CM129027, COSV101204461; ClinVar: not provided / pathogenic; called by muse, varscan2
- FOXA1 | c.798C>G p.F266L | Missense Mutation (SNP) | VAF 24/142 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51643681, COSV51647960; called by muse, mutect2
- GATA3 | c.878T>A p.M293K | Missense Mutation (SNP) | VAF 54/212 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM161496, COSV60515607, COSV60521489; called by muse, mutect2, varscan2
- JUN | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 23/201 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1184098204, COSV64664188, COSV64664376; called by muse, mutect2, varscan2
- NUP93 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 17/87 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs528073782, COSV57428317; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- SMAD2 | c.1391C>G p.S464* | Nonsense Mutation (SNP) | VAF 20/294 reads (7%) | hotspot (GDC flag); catalogued as COSV50992836, COSV50992894, COSV50993280; called by muse, mutect2
- ABCC10 | c.3957C>G p.L1319= (on ENST00000372530 / NM_001198934.2; = p.L1291= on NM_033450.2 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 26/250 reads (10%) | catalogued as COSV55084359; called by muse, mutect2
- ABCD4 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs1344217621; called by muse, mutect2
- ABI1 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as rs1459690002; called by muse, mutect2, varscan2
- ACTN4 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 34/457 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1172790414, COSV53149986; called by muse, mutect2
- ADCY10 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 108/358 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs996414328, COSV100896772; called by muse, mutect2, varscan2
- ADGRL3 | c.1687G>A p.E563K (on ENST00000506720 / NM_001322402.2; = p.E495K on NM_015236.6) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as rs759065083, COSV72229254; called by muse, mutect2, varscan2
- ADRA1B | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.005); catalogued as rs376068891; called by mutect2, varscan2
- AKAP8 | c.1438C>G p.H480D | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1340390312; called by muse, mutect2, varscan2
- ALG11 | c.746C>A p.S249Y | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV73000813; called by muse, mutect2
- ALK | c.2239G>A p.G747R | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs762395127, COSV66569083; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALMS1 | c.12463-1G>A p.X4155_splice | Splice Site (SNP) | VAF 18/285 reads (6%) | catalogued as COSV52524883; called by muse, mutect2
- ANK1 | c.1801-1G>A p.X601_splice | Splice Site (SNP) | VAF 41/354 reads (12%) | catalogued as COSV55883338; called by muse, mutect2, varscan2
- ANKRD11 | c.2306C>G p.S769* | Nonsense Mutation (SNP) | VAF 12/116 reads (10%) | catalogued as COSV56374078, COSV99968018; called by muse, mutect2, varscan2
- ANKRD30A | c.1307C>T p.S436F (on ENST00000611781; = p.S380F on NM_052997.2) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.272); catalogued as COSV64617464; called by muse, mutect2
- ANKRD34A | c.338C>G p.S113W | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100041288, COSV100041371, COSV60162212; called by muse, mutect2, varscan2
- ANKRD35 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.464); catalogued as rs1311132194; called by muse, mutect2
- ANTKMT | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.121); catalogued as rs1439313528; called by muse, mutect2, varscan2
- AP3B1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54877546; called by muse, mutect2
- AR | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); catalogued as rs764684648, COSV65954300; called by muse, mutect2
- ARAP1 | c.3823G>A p.D1275N (on ENST00000393609 / NM_001040118.2; = p.D1030N on NM_015242.4) | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1434066129; called by muse, mutect2, varscan2
- ARHGAP35 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV68334387; called by muse, mutect2
- ARHGAP9 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.001); catalogued as rs377740614; called by muse, mutect2, varscan2
- ARHGEF11 | c.540G>C p.Q180H | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV63810209; called by muse, mutect2
- ARHGEF7 | c.2366C>G p.S789C (on ENST00000375741 / NM_001113511.2; = p.S768C on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV54542502; called by muse, mutect2
- ARID1A | c.1910C>G p.S637C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV61380895; called by muse, varscan2
- ARID1A | c.4270C>T p.Q1424* | Nonsense Mutation (SNP) | VAF 18/187 reads (10%) | catalogued as COSV61373918, COSV61374195; called by muse, mutect2
- ARMCX4 | c.744G>T p.M248I (on ENST00000433011; = p.M144I on NM_001256155.2) | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.892); catalogued as COSV100708172; called by muse, mutect2
- ARRDC3 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.138); catalogued as COSV54364976; called by muse, mutect2
- ATP8B2 | c.465-3C>T | Splice Region (SNP) | VAF 21/249 reads (8%) | catalogued as COSV100527841; called by muse, mutect2
- B4GALNT2 | c.947-1G>C p.X316_splice | Splice Site (SNP) | VAF 6/92 reads (7%) | catalogued as COSV55925428, COSV55926428; called by muse, mutect2
- BCAN | c.2278G>C p.D760H | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1329743004; called by muse, mutect2, varscan2
- BRCA2 | c.4009G>C p.D1337H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV101204526; called by muse, mutect2
- BRWD1 | c.3206C>G p.S1069C | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV100312952; called by muse, mutect2
- BRWD3 | c.2855G>C p.G952A | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100956064; called by muse, mutect2, varscan2
- C19orf67 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0.02); catalogued as rs1279282504; called by muse, mutect2, varscan2
- C6orf118 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.118); catalogued as rs747009526, COSV57814508; called by muse, mutect2, varscan2
- C8orf34 | c.836A>G p.N279S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.359); catalogued as COSV100447901; called by muse, mutect2, varscan2
- CA13 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.066); catalogued as COSV100410315; called by muse, mutect2, varscan2
- CACNA1B | c.3364C>T p.R1122W | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs201227447, COSV53116181; called by muse, varscan2
- CAND2 | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1455308174; called by muse, mutect2
- CBL | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs767559244, COSV99081295; called by muse, mutect2
- CCDC168 | c.13228G>A p.D4410N | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.728); catalogued as rs1449620679; called by muse, mutect2
- CCDC88C | c.4894G>A p.E1632K | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.415); catalogued as rs377095559; called by muse, mutect2, varscan2
- CCDC88C | c.1071C>G p.I357M | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as rs771601735; called by muse, mutect2, varscan2
- CCNI2 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1344689144; called by muse, mutect2, varscan2
- CDH1 | c.26C>A p.S9* | Nonsense Mutation (SNP) | VAF 37/155 reads (24%) | catalogued as COSV55728625, COSV55737291; called by muse, mutect2, varscan2
- CDK7 | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV56513474; called by muse, mutect2, varscan2
- CHD4 | c.1354G>A p.D452N (on ENST00000357008 / NM_001363606.2; = p.D465N on NM_001273.5) | Missense Mutation (SNP) | VAF 22/297 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV58898967; called by muse, mutect2
- CHD7 | c.538C>G p.Q180E | Missense Mutation (SNP) | VAF 18/520 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as CM060209; called by muse, mutect2
- CIT | c.3100G>A p.D1034N | Missense Mutation (SNP) | VAF 28/302 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as rs1565959271; called by muse, mutect2
- CLASP1 | c.3132G>C p.Q1044H | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55331383; called by muse, mutect2, varscan2
- CNOT4 | c.1448G>A p.R483Q (on ENST00000315544 / NM_001190848.1; = p.R480Q on NM_013316.4) | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs549327841, COSV59651090; called by muse, mutect2, varscan2
- COA8 | c.146G>A p.R49K | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.018); catalogued as rs770615873; called by muse, mutect2, varscan2
- COL18A1 | c.3526G>A p.E1176K (on ENST00000359759 / NM_130444.3; = p.E941K on NM_030582.4) | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as rs1432696137; called by muse, mutect2
- COL1A1 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 51/386 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1191323992; called by muse, mutect2, varscan2
- COL27A1 | c.113C>G p.S38C | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.533); catalogued as COSV61927415; called by mutect2, varscan2
- COL4A5 | c.4039G>A p.E1347K | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100087501, COSV60364857; called by muse, mutect2, varscan2
- CPE | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as rs1242610459, COSV68579815, COSV68580216; called by muse, mutect2, varscan2
- CPLANE1 | c.8631-3C>G | Splice Region (SNP) | VAF 5/85 reads (6%) | catalogued as COSV57070613; called by muse, mutect2
- CRYBA1 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.899); catalogued as rs778307276, COSV99836982; called by muse, mutect2, varscan2
- CSF2RB | c.847G>C p.D283H | Missense Mutation (SNP) | VAF 20/550 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.176); catalogued as COSV53256600; called by muse, mutect2
- CYP27A1 | c.1578C>G p.F526L | Missense Mutation (SNP) | VAF 38/396 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV51468710; called by muse, mutect2
- DCDC1 | c.432G>A p.L144= | Splice Region (SNP) | VAF 10/98 reads (10%) | catalogued as COSV60833284; called by mutect2, varscan2
- DCHS1 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 57/496 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100201494; called by muse, mutect2, varscan2
- DCN | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.496); catalogued as COSV50006263; called by muse, mutect2
- DGKI | c.880C>A p.H294N | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55950828; called by muse, mutect2, varscan2
- DGUOK | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 30/350 reads (9%) | catalogued as rs1169743267, CM113282, COSV51203587; called by muse, mutect2
- DLC1 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as COSV52321053; called by muse, mutect2
- DMD | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV63756147; called by muse, mutect2, varscan2
- DNAH3 | c.9322G>C p.D3108H | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54515747; called by muse, mutect2
- DNM2 | c.774C>A p.F258L | Missense Mutation (SNP) | VAF 54/600 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs760953625, COSV58968612; called by muse, mutect2
- DNTTIP2 | c.204G>C p.K68N | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as rs1475805714, COSV63283831; called by muse, mutect2
- DPEP3 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.279); catalogued as rs867141954, COSV52052632; called by muse, mutect2, varscan2
- DUOX1 | c.128G>T p.R43I | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as COSV50993345; called by muse, mutect2
- DYM | c.947-1G>C p.X316_splice | Splice Site (SNP) | VAF 48/186 reads (26%) | catalogued as COSV99492331; called by muse, mutect2, varscan2
- DYNC1LI2 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99263251; called by muse, mutect2, varscan2
- EEFSEC | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV54629121; called by muse, mutect2
- EGR4 | c.794C>T p.S265L (on ENST00000545030; = p.S162L on NM_001965.4) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV101474283, COSV71532004; called by muse, mutect2, varscan2
- EHD3 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV100434680; called by muse, mutect2
- EHMT1 | c.2948C>G p.S983C | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as rs763031759; called by muse, mutect2, varscan2
- EIF2B4 | c.665C>G p.S222C (on ENST00000347454 / NM_001034116.2; = p.S221C on NM_015636.3) | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV52008877; called by muse, mutect2
- EIF3J | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.101); catalogued as rs1245026997; called by muse, mutect2
- ELF1 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as rs956883787, COSV53499445; called by muse, mutect2
- EPHA5 | c.1067G>A p.R356K | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs943944162; called by muse, mutect2, varscan2
- ERICH6 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV55803081; called by muse, mutect2, varscan2
- ESYT3 | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 70/276 reads (25%) | catalogued as rs184387509, COSV67441268; called by muse, mutect2, varscan2
- EXOSC6 | c.25C>G p.R9G | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.656); catalogued as rs531804444; called by muse, mutect2, varscan2
- FAM111A | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 25/327 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV64655542; called by muse, mutect2
- FAM166A | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 20/171 reads (12%) | catalogued as rs767750157, COSV100458175; called by muse, mutect2, varscan2
- FAM47A | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.461); catalogued as rs1477454448, COSV60498040; called by mutect2, varscan2
- FASTKD2 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 15/306 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.084); catalogued as rs886055506, COSV52700211; ClinVar: uncertain significance; called by muse, mutect2
- FAT3 | c.6163G>A p.E2055K | Missense Mutation (SNP) | VAF 75/328 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV53183842; called by muse, mutect2, varscan2
- FBXO4 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV55853588; called by muse, mutect2
- FBXO41 | c.2607C>G p.I869M | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1333880748; called by muse, mutect2, varscan2
- FBXW5 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 42/514 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774723521, COSV99812312; called by muse, mutect2
- FCRL6 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV58942820; called by muse, mutect2, varscan2
- FCRLB | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV61059912; called by muse, mutect2, varscan2
- FGF14 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as rs760595879, COSV65944703; ClinVar: uncertain significance; called by muse, mutect2
- FIBP | c.947C>G p.S316C (on ENST00000338369 / NM_198897.2; = p.S309C on NM_004214.5) | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.573); catalogued as COSV57172146; called by muse, mutect2
- FUT8 | c.1683G>C p.K561N (on ENST00000360689 / NM_001371534.1; = p.K398N on NM_004480.4) | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV61285071; called by muse, mutect2, varscan2
- GABRA6 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 11/247 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1240605914, COSV50877401; called by muse, mutect2
- GABRG2 | c.592C>G p.P198A | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100729648; called by muse, mutect2
- GFAP | c.973C>G p.Q325E | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV53650289; called by muse, mutect2
- GLI1 | c.2082G>C p.E694D | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57358559, COSV57361908; called by muse, mutect2
- GLIPR1L2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0.148); catalogued as COSV57554182; called by muse, mutect2
- GLRX2 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1180553885; called by muse, mutect2, varscan2
- GOLGA8R | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.145); catalogued as rs1465454972; called by muse, mutect2, varscan2
- GPA33 | c.193C>G p.H65D | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.346); catalogued as rs963515945; called by muse, varscan2
- GPI | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 51/475 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1209609704, COSV99875114; called by muse, mutect2, varscan2
- GRK4 | c.1202G>C p.R401T (on ENST00000398052 / NM_182982.3; = p.R369T on NM_005307.3) | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61669116, COSV61670993; called by muse, mutect2
- GRM7 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV63166369; called by muse, mutect2
- GSDMD | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV52797020; called by muse, mutect2
- GTF2H4 | c.135C>T p.F45= | Splice Region (SNP) | VAF 7/93 reads (8%) | catalogued as rs963810596; called by muse, mutect2
- H3C8 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); catalogued as COSV59952536; called by muse, mutect2
- HDAC6 | c.3421G>C p.E1141Q | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57806957; called by muse, mutect2
- HEATR5B | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs568836140; called by mutect2, varscan2
- HLA-A | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.993); catalogued as rs199474415; called by muse, mutect2
- IFNA13 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1214672516, COSV71924467, COSV71924570; called by muse, mutect2
- IFT74 | c.305+1G>A p.X102_splice | Splice Site (SNP) | VAF 22/78 reads (28%) | catalogued as rs766986213; called by muse, mutect2, varscan2
- IGKV1D-43 | c.9G>A p.M3I | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs769103507; called by muse, mutect2, varscan2
- IGSF9B | c.2026C>A p.L676M | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100318481, COSV58068488, COSV58072530; called by muse, mutect2, varscan2
- IRAG1 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70213069; called by muse, mutect2
- IRAG2 | c.3435G>C p.L1145F (on ENST00000636465; = p.L190F on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63140948; called by muse, mutect2
- ISLR2 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 40/366 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as rs149170531; called by muse, mutect2
- ITGA3 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs142527278, COSV50306912; called by muse, mutect2, varscan2
- ITPR3 | c.305A>G p.K102R | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); catalogued as rs1361422534; called by muse, mutect2
- IYD | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.372); catalogued as rs899437964, COSV57600673; called by muse, mutect2
- KAZN | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.678); catalogued as rs773002622, COSV63207903; called by muse, mutect2, varscan2
- KCNA4 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1221664561, COSV60253620; called by muse, mutect2, varscan2
- KCNJ12 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 18/476 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV100055785, COSV59163385; called by muse, mutect2
- KIF21B | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs766404118; called by muse, mutect2, varscan2
- KLHDC8A | c.362C>G p.S121C | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV65678343; called by muse, mutect2
- KMT2C | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 27/501 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100074646, COSV51491956, COSV51503785; called by muse, mutect2
- KNDC1 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.05); catalogued as COSV58844357; called by muse, mutect2, varscan2
- KRT16 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 23/290 reads (8%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.958); catalogued as rs532092611; called by muse, mutect2
- LAMA2 | c.4664G>A p.R1555K | Missense Mutation (SNP) | VAF 61/352 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.05); catalogued as rs1314123853, COSV70356042; called by muse, mutect2, varscan2
- LAMA3 | c.9518C>G p.S3173C (on ENST00000313654 / NM_198129.4; = p.S1564C on NM_000227.6) | Missense Mutation (SNP) | VAF 44/474 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52542193; called by muse, mutect2
- LCA5 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV63973524; called by muse, mutect2, varscan2
- LIFR | c.1847C>T p.S616L | Missense Mutation (SNP) | VAF 19/382 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54689641; called by muse, mutect2
- LIN28B | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV61493873; called by muse, mutect2
- LONP1 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as rs751508398; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LPCAT1 | c.1023C>T p.L341= | Splice Region (SNP) | VAF 8/85 reads (9%) | catalogued as rs780303802, COSV52038496; called by muse, mutect2, varscan2
- LRP1B | c.12020C>G p.S4007C | Missense Mutation (SNP) | VAF 22/295 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV67273514; called by muse, mutect2
- LRRC27 | c.1070G>C p.R357T | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV104414773; called by muse, mutect2
- LUZP4 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs141415241; called by muse, mutect2
- MAMDC4 | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs905821956; called by muse, mutect2
- MARCHF4 | c.1164G>C p.L388F | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56109056; called by muse, mutect2, varscan2
- MBD6 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.009); catalogued as rs1227229677; called by muse, mutect2
- MCF2L2 | c.2818G>C p.E940Q | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV61051491; called by muse, mutect2
- MKRN3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 40/399 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.306); catalogued as rs1566764735; called by muse, mutect2
- MLLT10 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756983501; called by muse, mutect2, varscan2
- MS4A14 | c.677G>C p.R226T | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100279941; called by muse, mutect2
- MUC16 | c.25168G>A p.E8390K | Missense Mutation (SNP) | VAF 92/394 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs746342432, COSV67490499; called by muse, mutect2, varscan2
- MUC4 | c.11185C>G p.L3729V | Missense Mutation (SNP) | VAF 19/433 reads (4%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.374); catalogued as rs754936209; called by muse, mutect2
- MUC5B | c.10310C>G p.S3437C | Missense Mutation (SNP) | VAF 62/848 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV101499950; called by muse, mutect2
- MYCBP2 | c.8562G>C p.L2854F (on ENST00000357337; = p.L2892F on NM_015057.5) | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.351); catalogued as COSV62018755; called by muse, mutect2, varscan2
- MYRIP | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV56862753; called by muse, mutect2, varscan2
- N4BP2L1 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.831); catalogued as COSV58412811; called by mutect2, varscan2
- NANOG | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV99981588; called by muse, mutect2
- NAP1L2 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.74); catalogued as rs1394206855, COSV65172543; called by muse, mutect2
- NCAM2 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV53105317; called by muse, mutect2, varscan2
- NDFIP2 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV54526438; called by muse, mutect2, varscan2
- NDST2 | c.2221C>G p.L741V | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV55213197; called by muse, mutect2, varscan2
- NDUFAF4 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60214211; called by muse, mutect2, varscan2
- NELFA | c.1057G>C p.E353Q (on ENST00000542778; = p.E342Q on NM_005663.5) | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.964); catalogued as rs868024863; called by muse, mutect2
- NELFA | c.465G>C p.L155F (on ENST00000542778; = p.L144F on NM_005663.5) | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61606741; called by muse, mutect2, varscan2
- NFE2L3 | c.1649C>G p.S550C | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV50230495; called by muse, mutect2
- NFX1 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 25/333 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV59310362; called by muse, mutect2
- NINL | c.3004G>C p.E1002Q | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as COSV54001337; called by muse, mutect2, varscan2
- NKD1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.879); catalogued as rs375195685; called by muse, mutect2, varscan2
- NLRP10 | c.1039C>T p.L347F | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100150015; called by muse, mutect2
- NLRP3 | c.1154C>G p.S385C | Missense Mutation (SNP) | VAF 19/429 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV60219943; called by muse, mutect2
- NOP9 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 25/312 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs976311505; called by muse, mutect2
- NOX3 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV50150820, COSV50153016; called by muse, mutect2
- NRXN3 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1436613332; called by muse, mutect2
- NUP155 | c.311G>A p.C104Y (on ENST00000231498 / NM_153485.3; = p.C45Y on NM_004298.4) | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV51533290; called by muse, mutect2
- OBSCN | c.20249C>T p.S6750F | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62367518; called by muse, mutect2
- OR10A6 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs746513332, COSV59165628; called by muse, mutect2
- OR2D2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs767764812, COSV55058262; called by muse, mutect2
- OR2T2 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 114/1260 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV61619140; called by muse, varscan2
- OR2Z1 | c.867C>G p.I289M | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60691893; called by muse, mutect2, varscan2
- OR51G2 | c.466C>A p.R156S | Missense Mutation (SNP) | VAF 39/393 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs773289689, COSV100432236, COSV58993411; called by muse, mutect2, varscan2
- OR5AU1 | c.615C>G p.F205L | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV100436113; called by muse, mutect2, varscan2
- OSBPL6 | c.809C>G p.S270* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as COSV51931254; called by muse, mutect2, varscan2
- PANX2 | c.1546G>T p.D516Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV50302305; called by muse, mutect2, varscan2
- PCARE | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.359); catalogued as rs201791642; called by muse, mutect2
- PCDHGB4 | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 49/702 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53905215; called by muse, mutect2
- PDGFRA | c.1965G>C p.L655F | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57272642, COSV99957332; called by muse, mutect2
- PDIK1L | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 33/177 reads (19%) | catalogued as COSV65322355; called by muse, mutect2, varscan2
- PDILT | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.275); catalogued as rs1454578593; called by muse, mutect2
- PEX2 | c.633C>G p.I211M | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV63813033; called by muse, mutect2, varscan2
- PLCH1 | c.4499C>T p.S1500L (on ENST00000340059 / NM_001130960.2; = p.S1492L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/422 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58190010; called by muse, varscan2
- PLCH1 | c.4312C>T p.Q1438* (on ENST00000340059 / NM_001130960.2; = p.Q1430* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/337 reads (11%) | catalogued as rs1368753771, COSV58210304; called by muse, varscan2
- PNN | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1227792808; called by muse, mutect2, varscan2
- PNPT1 | c.1767G>A p.M589I | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1485878239; called by muse, mutect2, varscan2
- POGZ | c.4210G>A p.D1404N | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs761261088; called by muse, mutect2, varscan2
- POM121L12 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 28/395 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV68692951, COSV68693360; called by muse, mutect2
- POSTN | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV65714878; called by muse, mutect2, varscan2
- PPFIA4 | c.1677G>A p.M559I (on ENST00000447715; = p.E549K on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/514 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1348357515; called by muse, mutect2
- PPP1R13L | c.1847C>G p.S616C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62909052; called by muse, mutect2
- PPP1R13L | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs773951416; called by muse, mutect2, varscan2
- PPP2R5E | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61740736; called by muse, mutect2, varscan2
- PPP2R5E | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs373172813, COSV61741860, COSV61744329; called by mutect2, varscan2
- PRDM6 | c.1414C>G p.L472V | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV68337108; called by muse, mutect2, varscan2
- PRKN | c.1174A>G p.R392G | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.055); catalogued as COSV58292170; called by muse, mutect2
- PRR27 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 12/323 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.048); catalogued as COSV100748753; called by muse, mutect2
- PRR7 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as rs1314452424; called by muse, mutect2
- PSMB5 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 29/375 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs770354735, COSV100557409; called by muse, mutect2
- PTPRD | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV100644802, COSV61932388; called by muse, mutect2
- PTPRZ1 | c.6367G>A p.D2123N | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV101100672; called by muse, mutect2, varscan2
- PYGO2 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 14/110 reads (13%) | catalogued as COSV100868978; called by muse, mutect2, varscan2
- RAB32 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV62249151; called by muse, mutect2, varscan2
- RB1CC1 | c.3892G>C p.E1298Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99212437; called by muse, mutect2, varscan2
- RBM45 | c.340G>C p.D114H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53722765; called by muse, mutect2, varscan2
- RBPJL | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs1454972483, COSV99056344; called by muse, mutect2, varscan2
- RCAN1 | c.110C>A p.S37* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | catalogued as COSV58249993, COSV58250681; called by muse, mutect2
- REL | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV54367621; called by muse, varscan2
- RFX6 | c.2217C>G p.F739L | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100263942; called by muse, mutect2
- RNF213 | c.8467C>T p.R2823W | Missense Mutation (SNP) | VAF 26/329 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs758812497; called by muse, mutect2
- RP1 | c.2521G>C p.E841Q | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV99609282; called by muse, mutect2
- RSPO1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 51/502 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs1557429580; called by muse, mutect2, varscan2
- RSPRY1 | c.1141G>C p.D381H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV68028945; called by muse, varscan2
- RTF2 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1316538931; called by muse, mutect2, varscan2
- SARDH | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100898249; called by muse, mutect2, varscan2
- SEC23IP | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 32/274 reads (12%) | catalogued as rs1287226925; called by muse, mutect2, varscan2
- SENP7 | c.1993C>T p.Q665* | Nonsense Mutation (SNP) | VAF 8/126 reads (6%) | catalogued as COSV58610057; called by muse, mutect2
- SERPINF2 | c.1171G>A p.V391M | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs376458796; called by muse, mutect2, varscan2
- SETBP1 | c.2620G>C p.D874H | Missense Mutation (SNP) | VAF 84/357 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56315090; called by muse, mutect2, varscan2
- SF3B2 | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as COSV57698197; called by muse, mutect2
- SH3D21 | c.746G>A p.R249Q (on ENST00000453908 / NM_001162530.2; = p.R138Q on NM_024676.5) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as rs149641597; called by mutect2, varscan2
- SKI | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 29/287 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66013818; called by muse, mutect2
- SLC15A2 | c.1393C>T p.H465Y | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV55200948, COSV99815053; called by muse, mutect2, varscan2
- SLC25A20 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs553582613; called by muse, mutect2
- SLC25A52 | c.766G>A p.E256K (on ENST00000672005; = p.E246K on NM_001034172.4) | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV52503490; called by mutect2, varscan2
- SLC26A11 | c.1035C>T p.I345= | Splice Region (SNP) | VAF 22/228 reads (10%) | catalogued as rs367934688; called by muse, mutect2
- SLC38A3 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.394); catalogued as rs1437118005; called by muse, mutect2
- SLC4A2 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV100055786; called by muse, mutect2, varscan2
- SLC5A1 | c.925C>G p.H309D | Missense Mutation (SNP) | VAF 61/535 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV56687360; called by muse, mutect2, varscan2
- SLC5A2 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 26/385 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1032587663, COSV57891982; called by muse, mutect2
- SLC6A9 | c.727C>T p.R243W (on ENST00000360584 / NM_201649.4; = p.R189W on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/359 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.663); catalogued as rs774340135, COSV62211007; called by muse, mutect2, varscan2
- SLC7A3 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1160933947; called by muse, mutect2, varscan2
- SMARCA2 | c.2564G>A p.R855Q | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1471482709, CM1311957, COSV61804436; called by muse, mutect2
- SMC6 | c.1574C>G p.S525C | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as rs750045170; called by muse, mutect2, varscan2
- SMPD4 | c.1704G>C p.K568N (on ENST00000409031 / NM_017951.4; = p.K539N on NM_017751.4) | Missense Mutation (SNP) | VAF 22/283 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99045472; called by muse, mutect2
- SNTG2 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.563); catalogued as rs759624529, COSV58011476; called by muse, mutect2, varscan2
- SOX3 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 18/504 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV65168511; called by muse, mutect2
- SOX7 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as rs957447009; called by muse, mutect2, varscan2
- SPAG4 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV100958302; called by muse, mutect2, varscan2
- SYNE1 | c.17338C>T p.R5780W (on ENST00000367255 / NM_182961.4; = p.R5709W on NM_033071.3) | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs202041462; called by mutect2, varscan2
- TACR3 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1008776547, CM103249, COSV59199133; called by muse, mutect2, varscan2
- TBCE | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV64005290; called by muse, mutect2
- TBKBP1 | c.1809C>G p.I603M | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64654260; called by muse, mutect2, varscan2
- TEKT5 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765195831; called by muse, mutect2
- TET1 | c.6298G>T p.E2100* | Nonsense Mutation (SNP) | VAF 14/216 reads (6%) | catalogued as COSV65386655; called by muse, mutect2
- TIA1 | c.794C>T p.A265V (on ENST00000433529 / NM_001351511.1; = p.A254V on NM_022037.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57006229; called by muse, mutect2, varscan2
- TIMM23B | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as rs1306916836; called by muse, mutect2
- TLN2 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.716); catalogued as rs754986736, COSV60887517; called by muse, mutect2, varscan2
- TMCC3 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs1361776611; called by muse, mutect2, varscan2
- TMEM123 | c.113T>G p.I38R | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs773768232, COSV63444208; called by muse, mutect2, varscan2
- TNPO3 | c.92C>G p.S31C | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55278805; called by muse, mutect2, varscan2
- TRAF3IP2 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 27/306 reads (9%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV60676412; called by muse, mutect2
- TRBV4-1 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.589); catalogued as rs1276605931; called by muse, mutect2, varscan2
- TRIM55 | c.838-1G>C p.X280_splice | Splice Site (SNP) | VAF 11/82 reads (13%) | catalogued as COSV52544378; called by muse, mutect2, varscan2
- TRIP10 | c.577C>G p.Q193E | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.559); catalogued as rs747588781; called by mutect2, varscan2
- TRPM8 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1310060155, COSV61224866; called by muse, mutect2
- TSPYL6 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as rs1306275078; called by muse, mutect2
- TTC6 | c.1309G>C p.E437Q (on ENST00000267368; = p.E1803Q on NM_001310135.3) | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.172); catalogued as COSV57447625; called by muse, mutect2
- TTN | c.52072G>A p.D17358N (on ENST00000591111; = p.D9934N on NM_003319.4) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | PolyPhen probably damaging (0.998); catalogued as COSV60276734; called by muse, mutect2, varscan2
- TTN | c.48202G>C p.E16068Q (on ENST00000591111; = p.E8644Q on NM_003319.4) | Missense Mutation (SNP) | VAF 13/254 reads (5%) | PolyPhen possibly damaging (0.743); catalogued as COSV100604364, COSV60004341; called by muse, mutect2
- TTN | c.42442G>C p.E14148Q (on ENST00000591111; = p.E6724Q on NM_003319.4) | Missense Mutation (SNP) | VAF 49/214 reads (23%) | PolyPhen benign (0.244); catalogued as rs755290030; called by muse, mutect2, varscan2
- TULP1 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 43/598 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as COSV57693200; called by muse, mutect2
- TXNIP | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs782282846, COSV65221216; called by muse, mutect2
- UBR1 | c.5125C>T p.H1709Y | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV51934210; called by muse, mutect2, varscan2
- UBR5 | c.6470G>A p.G2157E | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV55282854; called by muse, mutect2, varscan2
- UMOD | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 22/542 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.098); catalogued as COSV56779957; called by muse, mutect2
- UQCR10 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 34/177 reads (19%) | catalogued as rs377432442, COSV57458710; called by muse, mutect2, varscan2
- USP17L10 | c.610C>G p.Q204E | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1267057119; called by mutect2, varscan2
- VIPR2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as rs375596936; called by mutect2, varscan2
- VWCE | c.2381C>T p.P794L | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as rs777385860; called by muse, mutect2
- WDFY4 | c.7587G>A p.R2529= | Splice Region (SNP) | VAF 38/208 reads (18%) | catalogued as COSV55435990; called by muse, mutect2, varscan2
- WDR5 | c.855C>G p.I285M | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs756017391; called by muse, mutect2, varscan2
- XRCC5 | c.1314G>C p.L438F | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.478); catalogued as COSV67535912; called by muse, mutect2, varscan2
- YRDC | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV65988675; called by muse, mutect2, varscan2
- ZBED4 | c.3017C>T p.T1006M | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762308054; called by muse, mutect2, varscan2
- ZEB2 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 29/398 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as CM081853; called by muse, mutect2
- ZFAND1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV55106720; called by muse, mutect2, varscan2
- ZFR2 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs868802854; called by muse, mutect2, varscan2
- ZNF215 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.089); catalogued as rs762697859, COSV99549637; called by muse, mutect2, varscan2
- ZNF425 | c.893G>C p.G298A | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.755); catalogued as COSV65201464; called by muse, mutect2
- ZNF486 | c.510G>C p.K170N | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58720452; called by muse, mutect2
- ZNF518B | c.752C>T p.T251I | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs1291240098; called by muse, mutect2, varscan2
- ZNF687 | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1368156641, COSV55019113; called by muse, mutect2
- ZNF761 | c.1265G>C p.R422T | Missense Mutation (SNP) | VAF 79/333 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV61888332, COSV61889350; called by muse, mutect2, varscan2
- ZNF766 | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as COSV100765364; called by muse, mutect2
- ZNF816 | c.1405C>G p.Q469E | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.247); catalogued as rs1421340517; called by mutect2, varscan2
- ABCA13 | c.11428C>G p.L3810V | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.21); called by muse, mutect2
- ABCA3 | c.613+3G>A | Splice Region (SNP) | VAF 23/258 reads (9%) | called by muse, mutect2
- ABCC1 | c.1035C>G p.I345M | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- AC006059.2 | c.1555C>T p.H519Y | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.84); called by muse, varscan2
- ACACA | c.1410C>G p.F470L | Missense Mutation (SNP) | VAF 37/418 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); called by muse, mutect2
- ACACB | c.936G>C p.K312N | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- ACBD5 | c.266G>A p.G89E (on ENST00000375888 / NM_001352568.1; = p.G91E on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAM20 | c.1109G>A p.R370K | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0.01); called by muse, mutect2
- ADAMTSL4 | c.1330C>T p.Q444* | Nonsense Mutation (SNP) | VAF 59/797 reads (7%) | called by muse, mutect2
- ADCY8 | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.262); called by muse, mutect2
- ADCY8 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 36/498 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2
- ADGRA2 | c.3760G>A p.E1254K | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2
- ADHFE1 | c.1392G>A p.M464I | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- AGBL3 | c.1436C>G p.S479C | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AGT | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 54/804 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.282); called by muse, mutect2
- AGTR1 | c.720G>C p.K240N | Missense Mutation (SNP) | VAF 24/303 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2
- AHNAK | c.12259G>C p.A4087P | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.947); called by muse, mutect2
- AHNAK | c.8255C>T p.A2752V | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2
- AJM1 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ALDH9A1 | c.831G>C p.L277F | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ANGPT4 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2
- ANK2 | c.1849G>C p.E617Q | Missense Mutation (SNP) | VAF 17/284 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); called by muse, mutect2
- ANLN | c.3208G>A p.E1070K | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- AP2B1 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- AP3B1 | c.1125C>A p.F375L | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- APOC3 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 47/503 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2
- ARHGEF28 | c.1510C>G p.Q504E | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.106); called by muse, mutect2
- ARID1A | c.5483C>G p.S1828* | Nonsense Mutation (SNP) | VAF 11/199 reads (6%) | called by muse, mutect2
- ARMC10 | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ARRDC4 | c.54G>C p.K18N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by mutect2, varscan2
- ARSF | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ART3 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ASAH2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- ASB1 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- ASB14 | c.740C>G p.S247C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.934); called by muse, mutect2
- ASB15 | c.536C>G p.S179* | Nonsense Mutation (SNP) | VAF 34/346 reads (10%) | called by muse, mutect2
- ASH1L | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2
- ATAD2 | c.2666C>T p.P889L | Missense Mutation (SNP) | VAF 34/308 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ATM | c.3595G>C p.E1199Q | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- ATP10D | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ATP8B2 | c.1822C>G p.Q608E (on ENST00000672630; = p.Q575E on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ATR | c.7585G>A p.E2529K | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATXN1L | c.1039C>G p.Q347E | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.264); called by muse, mutect2
- BAZ2B | c.6334G>C p.E2112Q | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2
- BIRC6 | c.2212C>G p.P738A | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- BIRC6 | c.10351C>T p.Q3451* | Nonsense Mutation (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
- BRPF1 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BSCL2 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 44/440 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.326); called by muse, mutect2
- C12orf57 | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- C17orf80 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- C19orf67 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- C1orf112 | c.1537C>T p.Q513* | Nonsense Mutation (SNP) | VAF 12/114 reads (11%) | called by muse, mutect2, varscan2
- C1orf56 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 70/235 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- C21orf91 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C4orf54 | c.3416C>G p.S1139C | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.272); called by muse, mutect2
- CADPS2 | c.2831C>G p.S944C | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); called by muse, mutect2
- CAND1 | c.2029C>G p.L677V | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2
- CARNMT1 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 9/127 reads (7%) | called by muse, mutect2
- CBX1 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CCAR1 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.585); called by muse, mutect2
- CCDC120 | c.483G>C p.E161D | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- CCDC178 | c.1702G>C p.E568Q | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CCDC188 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CCDC74A | c.1136G>C p.*379Sext*24 | Nonstop Mutation (SNP) | VAF 11/181 reads (6%) | called by muse, mutect2
- CCNE2 | c.1163G>C p.G388A | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.062); called by muse, mutect2
- CD93 | c.461C>G p.P154R | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.247); called by muse, varscan2
- CDHR1 | c.1549G>C p.D517H | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CDKL3 | c.57G>A p.M19I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); called by muse, mutect2
- CDRT1 | c.108G>T p.W36C | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); called by mutect2, varscan2
- CEP120 | c.1661C>G p.S554C | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- CEP128 | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CERT1 | c.1021G>A p.D341N (on ENST00000405807 / NM_001130105.1; = p.D213N on NM_005713.3) | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2
- CFAP157 | c.753G>C p.E251D | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- CFAP43 | c.4864G>T p.E1622* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- CFH | c.2765C>T p.S922F | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- CHAF1A | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHD8 | c.6889G>C p.E2297Q (on ENST00000646647 / NM_001170629.2; = p.E2018Q on NM_020920.4) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- CHRDL1 | c.274C>T p.R92C (on ENST00000372045; = p.R98C on NM_145234.4) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CHUK | c.299G>C p.G100A | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- CIART | c.293G>C p.R98T | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CIT | c.1492A>T p.T498S | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CLCF1 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CLDN17 | c.659C>G p.S220C | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLK2 | c.1146+7G>A | Splice Region (SNP) | VAF 33/299 reads (11%) | called by muse, mutect2, varscan2
- CMYA5 | c.8474C>T p.S2825F | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); called by muse, mutect2
- COG2 | c.1347G>T p.Q449H | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- COL4A4 | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0.081); called by muse, mutect2
- CPA4 | c.912C>A p.F304L | Missense Mutation (SNP) | VAF 44/524 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.291); called by muse, mutect2
- CRACD | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 34/388 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2
- CRTAC1 | c.1407G>C p.K469N | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.022); called by muse, mutect2
- CTNNA2 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); called by muse, mutect2
- CTNNBL1 | c.1179C>G p.I393M | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CTR9 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- CUL4B | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CWC25 | c.531del p.K179Rfs*66 | Frame Shift Del (DEL) | VAF 9/92 reads (10%) | called by mutect2, pindel, varscan2
- CYP51A1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2
- DCAF8L2 | c.1141C>A p.Q381K | Missense Mutation (SNP) | VAF 36/372 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2
- DCLK2 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDB1 | c.2230G>C p.D744H | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.43); called by muse, mutect2
- DDX39A | c.72G>C p.E24D | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX4 | c.149G>C p.R50P | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- DHTKD1 | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- DHX34 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHX8 | c.1560G>C p.Q520H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIAPH1 | c.3623C>T p.S1208L | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- DLG5 | c.2602C>G p.L868V | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.009); called by muse, mutect2
- DMBT1 | c.5162G>C p.G1721A (on ENST00000338354 / NM_001377530.1; = p.G964A on NM_004406.3) | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAH6 | c.8416G>A p.D2806N | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- DNAH7 | c.2365C>T p.H789Y | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.121); called by muse, mutect2
- DNAH9 | c.8211G>C p.K2737N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by mutect2, varscan2
- DNAJC13 | c.1657G>C p.D553H | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAJC2 | c.1543G>C p.D515H | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- DOCK5 | c.816G>T p.E272D | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.009); called by mutect2, varscan2
- DOCK6 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- DRP2 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.967); called by muse, mutect2
- DTNB | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 23/200 reads (12%) | called by muse, mutect2, varscan2
- DUOX1 | c.3777C>G p.I1259M | Missense Mutation (SNP) | VAF 23/283 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2
- DYNC1H1 | c.2639G>C p.R880T | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.079); called by muse, mutect2
- DYRK2 | c.1171C>G p.P391A (on ENST00000344096 / NM_006482.3; = p.P318A on NM_003583.4) | Missense Mutation (SNP) | VAF 18/379 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EEF1AKMT2 | c.678C>G p.I226M | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- EGFLAM | c.2722G>A p.G908S (on ENST00000354891 / NM_001205301.2; = p.G900S on NM_152403.4) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EHBP1 | c.2230G>C p.E744Q | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2
- EIF2S3 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EIF4G2 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ELMO3 | c.1618G>C p.E540Q (on ENST00000652269; = p.E487Q on NM_024712.5) | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- ENDOU | c.487C>T p.L163F (on ENST00000422538 / NM_001172439.2; = p.L122F on NM_006025.4) | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- EPC2 | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPG5 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- EPN2 | c.710C>A p.S237Y | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.202); called by muse, mutect2
- ERCC6L2 | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EXOC6B | c.464G>A p.R155K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- EYA2 | c.1000G>C p.D334H | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- F2RL3 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 13/282 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- FAIM2 | c.511C>T p.L171F | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- FAM168B | c.37C>A p.P13T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM193A | c.3670G>C p.D1224H (on ENST00000324666 / NM_001256666.1; = p.D1183H on NM_003704.3) | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM200B | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- FARP2 | c.1304C>A p.S435Y | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.202); called by muse, mutect2
- FEM1C | c.1162G>C p.E388Q | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FEV | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FHL2 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- FKBP4 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- FLG | c.5684C>T p.S1895F | Missense Mutation (SNP) | VAF 145/962 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- FOXA1 | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FOXN3 | c.949G>A p.E317K (on ENST00000261302; = p.E295K on NM_005197.4) | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2
- FSIP2 | c.13365G>C p.Q4455H | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.398); called by muse, mutect2
- GBP1 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2, varscan2
- GLDC | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.085); called by muse, mutect2
- GLI1 | c.2719G>C p.E907Q | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- GMEB2 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GOPC | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- GPR21 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 17/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPR37 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- GPRASP1 | c.3556C>G p.Q1186E | Missense Mutation (SNP) | VAF 38/359 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GRIA2 | c.2226G>C p.M742I | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- GSTA2 | c.395A>G p.Y132C | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GSX1 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); called by muse, mutect2
- GTF3C5 | c.683A>T p.K228M | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- H6PD | c.1855G>A p.V619I | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- HACD3 | c.899C>G p.S300C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- HCN2 | c.1752C>G p.I584M | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HDGF | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- HDHD5 | c.589G>A p.E197K (on ENST00000336737 / NM_033070.3; = p.E167K on NM_017829.5) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEATR1 | c.6277G>A p.E2093K | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- HERC1 | c.6802G>A p.E2268K | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- HERC5 | c.583C>G p.Q195E | Missense Mutation (SNP) | VAF 34/343 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- HMX1 | c.391G>C p.D131H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- HOXD4 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 32/375 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.013); called by muse, mutect2
- HPF1 | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HRH1 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.015); called by muse, mutect2
- HS3ST4 | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HSPA12B | c.266G>C p.R89T | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2
- HTT | c.8137G>A p.E2713K | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- IFNA7 | c.569G>C p.*190Sext*11 | Nonstop Mutation (SNP) | VAF 15/121 reads (12%) | called by muse, mutect2, varscan2
- IGLV3-22 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 17/260 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- IL27RA | c.1714G>T p.E572* | Nonsense Mutation (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- IL7R | c.116C>G p.S39* | Nonsense Mutation (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- INO80 | c.1225G>T p.G409C | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2
- INTS7 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.766); called by muse, mutect2
- ISG20 | c.487C>G p.Q163E | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ISY1-RAB43 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.039); called by mutect2, varscan2
- ITGB4 | c.1384G>C p.E462Q | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.764); called by muse, mutect2
- ITSN1 | c.3181G>A p.E1061K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- JRKL | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2
- KALRN | c.6901G>C p.E2301Q (on ENST00000360013 / NM_001024660.4; = p.E604Q on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- KCNA4 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 14/222 reads (6%) | called by muse, mutect2
- KCNJ4 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 104/355 reads (29%) | called by muse, mutect2, varscan2
- KCNK4 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.034); called by muse, mutect2
- KCNS1 | c.1570C>G p.Q524E | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, varscan2
- KCTD13 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- KDM5C | c.1713G>A p.M571I | Missense Mutation (SNP) | VAF 52/479 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- KHDRBS3 | c.453C>G p.I151M | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KIAA2026 | c.835C>G p.Q279E | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); called by muse, mutect2
- KIFAP3 | c.513G>C p.L171F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2
- KL | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KLF10 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.244); called by muse, mutect2
- KMT2C | c.2865G>C p.L955F | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LAMB2 | c.4792G>A p.E1598K | Missense Mutation (SNP) | VAF 76/720 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- LCA5 | c.697G>C p.D233H | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- LCMT2 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.026); called by muse, mutect2
- LDLRAD3 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.276); called by muse, mutect2
- LIMA1 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.273); called by muse, mutect2
- LIPM | c.35C>G p.S12* | Nonsense Mutation (SNP) | VAF 13/115 reads (11%) | called by muse, mutect2, varscan2
- LMOD1 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LPP | c.1653G>C p.E551D | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRRC4 | c.743G>A p.W248* | Nonsense Mutation (SNP) | VAF 38/320 reads (12%) | called by muse, mutect2, varscan2
- LRRC4 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.075); called by muse, mutect2
- LRRC4 | c.119C>G p.S40* | Nonsense Mutation (SNP) | VAF 51/193 reads (26%) | called by mutect2, varscan2
- LRRC41 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRC8D | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 21/260 reads (8%) | called by muse, mutect2
- LRRTM2 | c.1040G>C p.G347A | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LRRTM2 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.085); called by muse, mutect2
- LTB4R2 | c.295G>A p.D99N (on ENST00000528054; = p.D68N on NM_019839.5) | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAP3K1 | c.1996C>T p.P666S | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- MAPK14 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MAPKAPK2 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 60/414 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MATN2 | c.1403del p.Q468Rfs*23 | Frame Shift Del (DEL) | VAF 41/216 reads (19%) | called by mutect2, pindel, varscan2
- MDN1 | c.9307G>C p.E3103Q | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2
- MED15 | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 19/157 reads (12%) | called by muse, mutect2, varscan2
- MED23 | c.2113G>A p.D705N | Missense Mutation (SNP) | VAF 13/226 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.267); called by muse, mutect2
- MEIOC | c.1839G>C p.Q613H | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.048); called by muse, mutect2
- METTL3 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- MEX3C | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- MLLT6 | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- MOGS | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MON2 | c.250C>G p.Q84E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- MR1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- MRPL3 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.027); called by muse, mutect2
- MS4A10 | c.336G>T p.M112I | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.049); called by muse, mutect2
- MSL2 | c.842C>G p.S281* | Nonsense Mutation (SNP) | VAF 20/256 reads (8%) | called by muse, mutect2
- MUC16 | c.18205G>C p.D6069H | Missense Mutation (SNP) | VAF 32/321 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- MXRA5 | c.7799T>C p.M2600T | Missense Mutation (SNP) | VAF 46/374 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.022); called by mutect2, varscan2
- MYBBP1A | c.375G>T p.K125N | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- MYCBPAP | c.2214G>C p.L738F | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO19 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- MYO1B | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- MYO1E | c.3037G>A p.E1013K | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MYORG | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 33/395 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- NANOS3 | c.503C>G p.S168C (on ENST00000397555; = p.S187C on NM_001098622.2) | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- NAV2 | c.5567C>G p.S1856* (on ENST00000396087 / NM_001244963.2; = p.S1797* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- NCOA5 | c.567G>C p.Q189H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- NDUFB10 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEURL1B | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 31/314 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- NFU1 | c.385G>A p.D129N (on ENST00000410022 / NM_001002755.4; = p.D105N on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.83); called by muse, mutect2
- NGEF | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- NGLY1 | c.1286G>A p.R429K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); called by muse, mutect2
- NGLY1 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHSL1 | c.1220C>G p.S407C | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NHSL2 | c.742C>T p.H248Y (on ENST00000510661; = p.H614Y on NM_001013627.2) | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.145); called by muse, mutect2
- NHSL2 | c.1150G>A p.E384K (on ENST00000510661; = p.E750K on NM_001013627.2) | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NHSL2 | c.1492G>A p.E498K (on ENST00000510661; = p.E864K on NM_001013627.2) | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.644); called by muse, mutect2
- NLGN1 | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.132); called by muse, mutect2
- NOX4 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.186); called by muse, mutect2
- NPAP1 | c.3399C>G p.F1133L | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.017); called by muse, mutect2
- NQO2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- NSD1 | c.2530G>C p.E844Q | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.532); called by muse, varscan2
- NUDT16L1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.31); called by muse, mutect2
- NUMA1 | c.42+1G>A p.X14_splice | Splice Site (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- NUP62 | c.1293G>C p.E431D | Missense Mutation (SNP) | VAF 54/595 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.417); called by muse, mutect2
- NUP88 | c.594-1G>C p.X198_splice | Splice Site (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- NWD2 | c.3487G>A p.E1163K | Missense Mutation (SNP) | VAF 39/391 reads (10%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- NWD2 | c.3734G>C p.C1245S | Missense Mutation (SNP) | VAF 44/324 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NXPH2 | c.551C>G p.S184C | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.868); called by muse, mutect2
- OBSCN | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- ONECUT2 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- OPN4 | c.1044C>G p.I348M | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR51B4 | c.333C>G p.I111M | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- OR5K2 | c.517C>G p.H173D | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.158); called by muse, mutect2
- OR7A17 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.636); called by muse, mutect2
- ORC6 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- PABPC4L | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 18/294 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PARG | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2
- PAX3 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.091); called by mutect2, varscan2
- PCDH9 | c.1407C>G p.F469L | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCNT | c.4208G>C p.R1403T | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PDE4DIP | c.2977C>T p.P993S | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2
- PGM3 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- PHB2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PHYH | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PIK3C2B | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 38/311 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PKD1L2 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PKHD1L1 | c.6971G>C p.G2324A | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PLCH1 | c.3386C>G p.S1129C (on ENST00000340059 / NM_001130960.2; = p.S1121C on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/338 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- PLIN2 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- PLK3 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); called by muse, mutect2
- PMS1 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 21/258 reads (8%) | called by muse, mutect2
- POLE | c.4407G>C p.E1469D | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.033); called by muse, mutect2
- PPFIBP2 | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPIAL4A | c.139C>G p.R47G | Missense Mutation (SNP) | VAF 60/270 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- PPOX | c.223-4G>T | Splice Region (SNP) | VAF 30/625 reads (5%) | called by muse, mutect2
- PPP1R26 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP2R5B | c.729C>G p.I243M | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); called by muse, mutect2
- PRDM4 | c.1961C>G p.S654C | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PRICKLE4 | c.1010C>G p.S337C (on ENST00000359201; = p.S377C on NM_013397.6) | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PROX1 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 25/277 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); called by muse, mutect2
- PRPF40B | c.778G>C p.E260Q (on ENST00000380281; = p.E254Q on NM_012272.3) | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.727); called by muse, mutect2
- PRRC2C | c.583C>T p.Q195* (on ENST00000367742; = p.Q193* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 20/237 reads (8%) | called by muse, mutect2
- PSMC1 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- PWWP2B | c.1295G>A p.R432K | Missense Mutation (SNP) | VAF 45/400 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASGRF2 | c.2780C>G p.S927* | Nonsense Mutation (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
- RB1CC1 | c.1381C>T p.H461Y | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RBM15 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- RBP3 | c.3204G>C p.W1068C | Missense Mutation (SNP) | VAF 20/339 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RCC1 | c.327G>C p.E109D | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RCN3 | c.287G>A p.W96* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | called by muse, varscan2
- RHBDD1 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- RND2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF187 | c.528G>C p.K176N | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- RNF19A | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RNF213 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 37/437 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2
- RNF213 | c.12382C>G p.P4128A | Missense Mutation (SNP) | VAF 33/410 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ROCK1 | c.1417C>G p.Q473E | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.102); called by muse, mutect2
- RPL38 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2
- RPRD2 | c.1685C>T p.S562L | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- RRP15 | c.414G>C p.K138N | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RSAD1 | c.569G>C p.G190A | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); called by muse, mutect2
- RTCA | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); called by muse, mutect2
- RTL1 | c.876C>A p.F292L | Missense Mutation (SNP) | VAF 28/367 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2
- RTN4 | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.057); called by muse, mutect2
- RUNDC3A | c.1309C>A p.P437T | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SACS | c.1120C>T p.H374Y | Missense Mutation (SNP) | VAF 34/361 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.102); called by muse, mutect2
- SAMD14 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.431); called by mutect2, varscan2
- SEL1L3 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SERBP1 | c.905C>G p.A302G (on ENST00000370995 / NM_001018067.2; = p.A281G on NM_015640.4) | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2
- SETD1A | c.3841G>C p.E1281Q | Missense Mutation (SNP) | VAF 21/269 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SF3A2 | c.749C>G p.S250C | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- SHPRH | c.2556G>T p.Q852H | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIK3 | c.1960C>G p.L654V (on ENST00000445177 / NM_001366686.2; = p.L612V on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- SIN3A | c.3462G>C p.K1154N | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2
- SIX5 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- SLAIN2 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC13A3 | c.1489G>C p.E497Q | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC1A5 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC22A18AS | c.263G>C p.R88T | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- SLC25A6 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- SLC38A5 | c.781A>G p.T261A | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.085); called by muse, mutect2
- SLC7A7 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SLCO3A1 | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 108/419 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCD3 | c.1243G>C p.D415H (on ENST00000262188 / NM_001003801.2; = p.D402H on NM_003078.4) | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SNX24 | c.397G>C p.V133L | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2
- SP110 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2
- SPATA18 | c.1453G>C p.E485Q | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPEN | c.10861C>G p.Q3621E | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2
- SPN | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2
- SPRED3 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2
- SRF | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SSTR2 | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 42/572 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.549); called by muse, mutect2
- ST18 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- STARD9 | c.10757G>C p.R3586T | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.022); called by muse, mutect2
- STARD9 | c.11197G>A p.D3733N | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- STRAP | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.156); called by muse, varscan2
- SUFU | c.996G>C p.Q332H | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- SUPT20H | c.1945C>A p.Q649K (on ENST00000350612 / NM_001014286.3; = p.Q650K on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- SUPT20HL1 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 43/435 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- SYCP2 | c.2833G>C p.D945H | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SYCP3 | c.153G>C p.E51D | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- TAB3 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- TANC2 | c.2016G>C p.K672N | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TASOR | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 19/128 reads (15%) | called by muse, mutect2, varscan2
- TASOR2 | c.5489C>G p.S1830C | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- TBC1D8 | c.2079C>G p.I693M | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TBPL2 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2
- TBX18 | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TCTN1 | c.863C>T p.S288F (on ENST00000551590 / NM_001173975.3; = p.S274F on NM_024549.6) | Missense Mutation (SNP) | VAF 38/349 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- THSD7B | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- TLR6 | c.2377G>T p.D793Y | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- TMCC1 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.017); called by muse, mutect2
- TMED8 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- TMEM102 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM121 | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.124); called by muse, mutect2
- TMEM132E | c.2101G>A p.E701K (on ENST00000321639; = p.E791K on NM_001304438.2) | Missense Mutation (SNP) | VAF 23/339 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, mutect2
- TMEM237 | c.10G>C p.D4H | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2
- TMPRSS3 | c.570G>A p.V190= | Splice Region (SNP) | VAF 50/632 reads (8%) | called by muse, mutect2
- TNIK | c.1859C>G p.S620C | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); called by muse, mutect2
- TNNI2 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.086); called by muse, mutect2
- TOMM6 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, varscan2
- TRIM13 | c.721G>C p.D241H | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- TRIM69 | c.1109C>G p.S370* (on ENST00000329464 / NM_182985.5; = p.S211* on NM_080745.5) | Nonsense Mutation (SNP) | VAF 8/212 reads (4%) | called by muse, mutect2
- TSHZ3 | c.2562G>C p.L854F | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TSPYL6 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 27/259 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TTLL3 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.025); called by muse, mutect2
- TTLL4 | c.3326C>G p.S1109* | Nonsense Mutation (SNP) | VAF 22/181 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.74729C>G p.S24910* (on ENST00000591111; = p.S17486* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 27/385 reads (7%) | called by muse, mutect2
- TUBGCP6 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 21/247 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.951); called by muse, mutect2
- TWF1 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- TYRO3 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- UACA | c.439C>G p.P147A | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- UBQLNL | c.305C>A p.S102Y | Missense Mutation (SNP) | VAF 26/321 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UBR2 | c.4735G>T p.E1579* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2
- UBR5 | c.5770C>G p.L1924V | Missense Mutation (SNP) | VAF 16/231 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- UGT1A6 | c.100C>G p.Q34E | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.158); called by muse, mutect2
- ULK4 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UNC79 | c.505G>C p.D169H | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2
- USH2A | c.6124G>A p.E2042K | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- USP21 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- USP6 | c.3729G>C p.L1243F | Missense Mutation (SNP) | VAF 41/321 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- USP6NL | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2
- USP9X | c.3001G>T p.E1001* | Nonsense Mutation (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2, varscan2
- UTRN | c.2545C>T p.L849F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- VCPIP1 | c.2869G>C p.D957H | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2
- VPS13A | c.145-1G>C p.X49_splice | Splice Site (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- VPS13A | c.1056G>A p.W352* | Nonsense Mutation (SNP) | VAF 19/216 reads (9%) | called by muse, mutect2
- VTCN1 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.01); called by muse, mutect2
- WASHC5 | c.716C>A p.S239* | Nonsense Mutation (SNP) | VAF 48/222 reads (22%) | called by muse, mutect2, varscan2
- WDFY4 | c.6004C>G p.Q2002E | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by muse, mutect2
- WHAMM | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.307); called by muse, mutect2
- WWC1 | c.3011A>G p.Q1004R | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- XIRP2 | c.3328G>C p.D1110H (on ENST00000628543; = p.D1285H on NM_152381.6) | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XPOT | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.492); called by muse, mutect2
- ZBED5 | c.972C>G p.I324M | Missense Mutation (SNP) | VAF 45/312 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ZBTB32 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 17/229 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.027); called by muse, mutect2
- ZBTB41 | c.2209G>C p.D737H | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ZBTB5 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 23/307 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZC3H11A | c.458C>G p.P153R | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFAND5 | c.260C>G p.S87* | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | called by muse, mutect2, varscan2
- ZFC3H1 | c.1864G>C p.E622Q | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2
- ZNF131 | c.937G>A p.E313K (on ENST00000509156 / NM_001330707.2; = p.E279K on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.152); called by muse, mutect2
- ZNF195 | c.1871A>C p.H624P (on ENST00000399602 / NM_001130520.3; = p.H552P on NM_007152.5) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- ZNF469 | c.3625G>C p.D1209H (on ENST00000437464; = p.D1237H on NM_001367624.2) | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by mutect2, varscan2
- ZNF501 | c.795G>C p.Q265H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- ZNF502 | c.38G>C p.R13T | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF502 | c.788G>C p.G263A | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2
- ZNF521 | c.2998G>A p.E1000K | Missense Mutation (SNP) | VAF 33/388 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF550 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 30/354 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.121); called by muse, mutect2
- ZNF700 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ZNF729 | c.3266C>A p.S1089* | Nonsense Mutation (SNP) | VAF 18/248 reads (7%) | called by muse, mutect2
- ZNF735 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2
- ZSCAN20 | c.2101C>T p.Q701* | Nonsense Mutation (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- ZSWIM8 | c.4078G>C p.E1360Q (on ENST00000605216 / NM_001242487.2; = p.E1365Q on NM_015037.3) | Missense Mutation (SNP) | VAF 13/283 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.563); called by muse, mutect2
- A2M | c.525C>T p.I175= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as rs761730698, COSV59383213; called by muse, varscan2
- ABCC1 | c.2220G>A p.V740= | Silent (SNP) | VAF 18/198 reads (9%) | called by muse, mutect2
- AC006538.2 | c.279G>A p.K93= | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- AC092143.1 | c.1488G>A p.T496= | Silent (SNP) | VAF 84/660 reads (13%) | catalogued as rs371662941; ClinVar: likely benign / benign; called by muse, varscan2
- ACE | c.3390C>T p.V1130= | Silent (SNP) | VAF 44/606 reads (7%) | catalogued as rs1173793027, COSV99327987; called by muse, mutect2
- ACTB | c.675A>G p.Q225= | Silent (SNP) | VAF 125/553 reads (23%) | called by muse, mutect2, varscan2
- ADGRE5 | c.2346C>G p.L782= (on ENST00000242786 / NM_078481.4; = p.L689= on NM_001784.5) | Silent (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- ADGRF4 | c.1941C>T p.F647= | Silent (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2
- ADGRV1 | c.13728G>A p.V4576= | Silent (SNP) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- AFF2 | c.1281G>A p.L427= | Silent (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2
- AGMO | c.891C>T p.V297= | Silent (SNP) | VAF 10/167 reads (6%) | called by muse, mutect2
- AK7 | c.1662C>T p.L554= | Silent (SNP) | VAF 28/281 reads (10%) | called by muse, mutect2, varscan2
- AKAP17A | c.1293G>A p.E431= | Silent (SNP) | VAF 81/274 reads (30%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.1557G>A p.L519= | Silent (SNP) | VAF 46/195 reads (24%) | called by muse, varscan2
- ALMS1 | c.6075C>G p.P2025= | Silent (SNP) | VAF 17/259 reads (7%) | called by muse, mutect2
- ALMS1 | c.11298G>A p.L3766= | Silent (SNP) | VAF 38/151 reads (25%) | called by muse, mutect2, varscan2
- ANGPTL8 | c.207C>T p.L69= | Silent (SNP) | VAF 25/308 reads (8%) | called by muse, mutect2
- ANK2 | c.4686G>A p.V1562= | Silent (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- ANLN | c.807G>A p.L269= | Silent (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
441 further variants in this file (0 protein-altering or splice-affecting, 289 silent, 152 other) are not listed here.
